Gene-level copy-number profile of tumor specimen ALCH-ADRX-TTP1-A from ALCHEMIST case ALCH-ADRX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 73.9 years (26,976 days).
Specimen ALCH-ADRX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b69549c-a0c3-4708-a7c1-83a513d66674.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADRX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/a1e6419e-9609-4715-819f-dbf884bfff02

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,086; copy number 2: 56,810; copy number 3: 434; copy number 4: 45; copy number 5: 1; copy number 6: 1; copy number 7: 2; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:239,085,827–239,085,926, 1 gene (within-gene range 0–2): MIR4441.
- chr3:153,129,074–153,129,640, 1 gene: AC117394.1.
- chr7:63,044,827–63,054,431, 1 gene: AC069285.2.
- chr8:143,915,153–143,976,734, 2 genes: PLEC, MIR661.
- chr10:114,423,770–114,427,398, 2 genes: RN7SL384P, AL133384.2.
- chr11:612,553–626,078, 2 genes: IRF7, CDHR5.
- chr11:68,891,276–68,940,602, 2 genes: MRPL21, IGHMBP2.
- chr19:3,052,910–3,063,107, 2 genes (within-gene range 0–2): AC005944.1, TLE5.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.
- chr20:62,952,707–62,969,585, 1 gene: SLC17A9.
- chr21:44,989,864–44,995,185, 2 genes: LINC00163, LINC00165.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,510,690–238,555,054, 1 gene, copy number 6: LINC01107.
- chr20:62,872,250–62,873,076, 1 gene, copy number 5: ARF4P2.
- chr21:43,446,601–43,479,534, 3 genes, copy number 7–14: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 1,012. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
